Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4784, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4784-01A (Primary Tumor).

[page 1 of 2]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

with right renal mass.

Specimens Submitted:

1: Kidney, right, tumor, partial nephrectomy

2: Kidney, right, mass, deep margin#2. excision

DIAGNOSIS:

1. Kidney, right, tumor, partial nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 1.5 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

Comment: This carcinoma is morphologically unusual in that it contains foci of papillary architecture with clear cell cytology.

2. Kidney, right, mass, deep margin#2. excision

Benign fragment of renal parenchyma with marked chronic inflammation

[page 2 of 2]
[REDACTED]

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]

Gross Description:

[REDACTED]

1) The specimen is received fresh for frozen section consultation, labeled "Right renal tumor, stitch marks deep margin" and consists of pink-tan soft tissue measuring from 2 x 1 x 1. Serial sections reveal a well-circumscribed, encapsulated nodule measuring 1.5 x 1.2 x 1.0 cm. Entirely submitted for frozen section. A section is given for TPS.

Summary of sections:
FSC - frozen section control
U - undesignated

[REDACTED]

2) The specimen is received fresh for frozen section consultation, labeled "Right renal mass, deep margin #2" and consists of a fragment of pink-tan soft tissue measuring 0.6 x 0.3 x 0.2 cm. Entirely submitted for frozen section.

Summary of sections:
FSC - frozen section control

Summary of Sections:

Part 1: Kidney, right, tumor, partial nephrectomy

Block	Sect. Site	PCs
1	FSC	1
2	U	4

Part 2: Kidney, right, mass, deep margin#2, excision [REDACTED]

Block	Sect. Site	PCs
1	fsc	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the Intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL NEOPLASM. DEEP MARGIN IS BENIGN. [REDACTED]
PERMANENT DIAGNOSIS: SAME
- 2) FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 6333ebbd-6cc2-4b74-af02-04a7ce21a725 (TCGA-BP-4784.126271E1-1435-4173-884C-F522FDC8581C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).